Gene-level copy-number profile of tumor specimen HCM-WCMC-0948-C67-01A from HCMI case HCM-WCMC-0948-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 84.0 years (30,697 days).
Specimen HCM-WCMC-0948-C67-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6a5cdaa-dd44-4850-bf83-49d0b08cfc09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0948-C67-11A (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/e8a3103a-7e95-45fa-89ef-8abcf970b25e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 600; copy number 1: 14,900; copy number 2: 32,252; copy number 3: 10,253; copy number 4: 623; copy number 5: 212; copy number 6: 27; copy number 8: 9; copy number 22: 2; copy number 24: 1; copy number 29: 3; copy number 33: 12; copy number 36: 18.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:163,494,442–163,520,539, 1 gene: TMA16.
- chr4:163,529,771–163,530,697, 1 gene (within-gene range 0–2): AC093788.1.
- chr9:71,804,283–71,804,826, 1 gene (within-gene range 0–2): AL671309.1.
- chr11:114,059,711–114,256,765, 2 genes (within-gene range 0–2): ZBTB16, AP002755.1.
- chr12:91,871,122–92,531,324, 16 genes: AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1.
- chr14:18,333,726–18,650,966, 17 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr21:7,744,962–8,987,430, 36 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 284 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:8,931,495–15,205,959, 150 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr3:36,685,040–37,217,988, 21 genes, copy number 5: RN7SKP227, DCLK3, HSPD1P6, LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3.
- chr3:39,808,914–40,309,698, 3 genes, copy number 5 (within-gene range 2–5): MYRIP, RNU4-56P, EIF1B-AS1.
- chr6:19,143,695–22,654,455, 36 genes, copy number 22–36: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1.
- chr8:103,500,696–104,256,094, 1 gene, copy number 5 (within-gene range 3–5): RIMS2.
- chr8:103,768,281–106,060,524, 22 genes, copy number 5: AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA.
- chr9:22,203,990–22,214,672, 1 gene, copy number 6: AL157937.1.
- chr11:67,056,847–67,072,017, 1 gene, copy number 5: RHOD.
- chr15:86,079,973–87,029,052, 1 gene, copy number 5 (within-gene range 2–10): AGBL1.
- chr15:86,295,649–86,988,426, 4 genes, copy number 5 (within-gene range 2–10): AGBL1-AS1, AC012229.1, AC016987.2, AC016987.1.
- chr19:27,638,483–28,727,777, 26 genes, copy number 6: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1.
- chr19:36,850,361–37,130,368, 9 genes, copy number 8 (within-gene range 3–8): ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2.
- chr19:48,394,875–48,599,425, 9 genes, copy number 5: GRIN2D, GRWD1, KCNJ14, AC008403.2, AC008403.1, CYTH2, LMTK3, AC008403.3, SULT2B1.

Autosomal genes at a single copy (total copy number 1): 12,559. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
